Somatic mutation profile of tumor specimen 0DRIW7 from CCDI case PBCGNR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 1.6 years (580 days).
Specimen 0DRIW7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ccc29a8-ef29-4d38-8312-15fcbc983bba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRIWH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43ee49d7-4693-4e0d-afd7-0171391b4674

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 4, Silent 4, Intron 3, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.724T>A p.C242S | Missense Mutation (SNP) | VAF 329/353 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519982, CM107067, COSV52660956, COSV52677021, COSV52760397, COSV52839973; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARHGAP31 | c.1631C>A p.A544D | Missense Mutation (SNP) | VAF 219/243 reads (90%) | SIFT tolerated (0.14); PolyPhen benign (0.312); catalogued as COSV99957939; called by muse, mutect2, varscan2
- ARRDC5 | c.91T>C p.Y31H (on ENST00000381781; = p.Y17H on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 363/403 reads (90%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.99); catalogued as rs1488711782, COSV67788069; called by muse, mutect2, varscan2
- CHRD | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 324/1188 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV99200237; called by muse, mutect2, varscan2
- IQUB | c.490T>A p.L164I | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs1374276177; called by muse, mutect2, varscan2
- MTUS2 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 56/1055 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs371733167; called by muse, mutect2
- REG3G | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 181/463 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55449435; called by muse, mutect2, varscan2
- USP1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs1182168994; called by muse, mutect2, varscan2
- ATG4D | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC168 | c.20432T>C p.I6811T | Missense Mutation (SNP) | VAF 48/674 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2
- CD34 | c.96T>G p.S32R | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP43 | c.866T>G p.L289* | Nonsense Mutation (SNP) | VAF 191/208 reads (92%) | called by muse, mutect2, varscan2
- GAD2 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK5 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 406/446 reads (91%) | SIFT tolerated (0.57); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- MUC16 | c.14312C>G p.S4771C | Missense Mutation (SNP) | VAF 466/523 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- OR2L13 | c.230T>A p.V77D | Missense Mutation (SNP) | VAF 373/727 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PHRF1 | c.3334A>T p.R1112W (on ENST00000264555 / NM_001286581.2; = p.R1111W on NM_020901.4) | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SERPINB2 | c.382A>T p.K128* | Nonsense Mutation (SNP) | VAF 227/446 reads (51%) | called by muse, mutect2, varscan2
- TRIML2 | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 72/1090 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.257); called by muse, mutect2
- ZNF572 | c.1398A>T p.K466N | Missense Mutation (SNP) | VAF 108/611 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CAMSAP3 | c.2124C>T p.A708= | Silent (SNP) | VAF 123/133 reads (92%) | catalogued as rs1219909400; called by muse, mutect2, varscan2
- FLG | c.8053C>A p.R2685= | Silent (SNP) | VAF 76/233 reads (33%) | catalogued as rs754727774; called by muse, mutect2, varscan2
- HOXD12 | c.534G>A p.A178= | Silent (SNP) | VAF 392/431 reads (91%) | catalogued as COSV66832804; called by muse, mutect2, varscan2
- REG3G | c.111G>T p.R37= | Silent (SNP) | VAF 264/902 reads (29%) | catalogued as COSV55450124, COSV55451006; called by muse, mutect2, varscan2
- ANKIB1 | c.2284-89_2284-68del | Intron (DEL) | VAF 35/200 reads (18%) | called by mutect2, pindel, varscan2
- CDH6 | c.*2C>A | 3'UTR (SNP) | VAF 33/169 reads (20%) | catalogued as COSV99419722; called by muse, mutect2, varscan2
- CNDP1 | c.-78T>A | 5'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- MEX3D | c.*118G>T | 3'UTR (SNP) | VAF 17/20 reads (85%) | called by muse, mutect2, varscan2
- MEX3D | c.*117G>T | 3'UTR (SNP) | VAF 17/20 reads (85%) | called by muse, mutect2, varscan2
- MYO1C | c.1798-95C>G | Intron (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- NBL1 | c.*267G>T | 3'UTR (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- PRDM5 | c.743+31A>G | Intron (SNP) | VAF 25/237 reads (11%) | called by muse, mutect2, varscan2
